Somatic mutation profile of tumor specimen TCGA-ER-A19T-06A (aliquot TCGA-ER-A19T-06A-11D-A19A-08) from TCGA case TCGA-ER-A19T, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acral lentiginous melanoma, malignant; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 51.5 years (18,802 days).
Specimen TCGA-ER-A19T-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 311f12da-2090-4443-8662-53ede0d838bb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ER-A19T-10A (Blood Derived Normal), aliquot TCGA-ER-A19T-10A-01D-A19A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ff51cf62-4c7c-4dc1-b527-c1fbe9d4ec89

The open-access MAF lists 45 somatic variants for this specimen: 38 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 30, Silent 7, Nonsense Mutation 4, Frame Shift Del 2, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACOXL | c.1397dup p.H467Pfs*35 (on ENST00000389811 / NM_001371254.1; = p.H437Pfs*35 on NM_001142807.4) | Frame Shift Ins (INS) | VAF 15/84 reads (18%) | catalogued as rs761069344; called by mutect2, pindel, varscan2
- AFDN | c.857G>T p.G286V | Missense Mutation (SNP) | VAF 50/169 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60058617; called by muse, mutect2, varscan2
- AGO2 | c.1652A>G p.N551S | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.388); catalogued as COSV55053326; called by muse, mutect2, varscan2
- AP2M1 | c.508C>T p.R170W | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53050443; called by mutect2, varscan2
- BRIP1 | c.1391C>G p.A464G | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.087); catalogued as COSV52010084; called by muse, mutect2, varscan2
- CD163 | c.199A>G p.K67E | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.975); catalogued as COSV63138251; called by muse, varscan2
- CDHR2 | c.1637T>C p.L546P | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56146146; called by muse, mutect2
- CEL | c.1547C>T p.T516M (on ENST00000673714; = p.T513M on NM_001807.6) | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs762461399, COSV60826847; called by mutect2, varscan2
- CRB1 | c.2490C>G p.I830M | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.056); catalogued as COSV66334402; called by muse, mutect2, varscan2
- CTDSPL2 | c.56G>A p.R19H | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.005); catalogued as rs779587261, COSV52948373; called by mutect2, varscan2
- DDX10 | c.2247+2T>C p.X749_splice | Splice Site (SNP) | VAF 15/30 reads (50%) | catalogued as COSV59440838; called by muse, mutect2, varscan2
- DIS3 | c.755G>C p.R252T | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated (0.48); PolyPhen benign (0.039); catalogued as COSV66705859; called by muse, mutect2, varscan2
- DPPA2 | c.5C>G p.S2* | Nonsense Mutation (SNP) | VAF 19/35 reads (54%) | catalogued as COSV72118353; called by muse, mutect2, varscan2
- EVPL | c.3616A>G p.T1206A | Missense Mutation (SNP) | VAF 11/155 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56916716; called by muse, mutect2
- EZHIP | c.1183C>G p.R395G | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.028); catalogued as COSV100539773; called by muse, mutect2, varscan2
- FOLH1 | c.2068G>A p.V690I | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT tolerated (0.92); PolyPhen benign (0.041); catalogued as COSV57057518; called by muse, mutect2, varscan2
- JOSD2 | c.107A>C p.Q36P | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV65350933; called by muse, mutect2, varscan2
- LCN15 | c.128C>A p.A43E | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.46); catalogued as COSV60211500; called by muse, mutect2, varscan2
- LPA | c.5152C>T p.Q1718* | Nonsense Mutation (SNP) | VAF 12/40 reads (30%) | catalogued as rs1421825841, COSV60313879; called by mutect2, varscan2
- MARCKSL1 | c.313T>C p.F105L | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.622); catalogued as COSV61482479; called by mutect2, varscan2
- MYO5A | c.971G>C p.G324A | Missense Mutation (SNP) | VAF 55/386 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as COSV62565327; called by muse, mutect2, varscan2
- NDUFAF2 | c.213G>A p.W71* | Nonsense Mutation (SNP) | VAF 89/232 reads (38%) | catalogued as COSV56937349; called by muse, mutect2, varscan2
- NLRP2 | c.1984C>A p.L662I | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as COSV54753138; called by mutect2, varscan2
- ODF3 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs747210196, COSV57293180; called by mutect2, varscan2
- OR2A5 | c.12T>A p.N4K | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV68739225; called by muse, mutect2, varscan2
- OVCH2 | c.901G>C p.G301R | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV101491928, COSV71953224; called by muse, mutect2, varscan2
- PGK2 | c.435T>A p.D145E | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs777833062, COSV59163183; called by muse, mutect2, varscan2
- PITPNM1 | c.1351G>C p.A451P | Missense Mutation (SNP) | VAF 38/460 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as COSV62710132; called by muse, mutect2
- PLSCR4 | c.415A>G p.T139A | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.253); catalogued as rs1192777888, COSV61609165; called by muse, mutect2, varscan2
- PPFIBP2 | c.2260del p.R754Afs*24 | Frame Shift Del (DEL) | VAF 22/65 reads (34%) | catalogued as COSV55081330; called by mutect2, pindel, varscan2
- RELN | c.1900C>T p.R634* | Nonsense Mutation (SNP) | VAF 7/87 reads (8%) | catalogued as COSV59019305, COSV59025265; called by muse, mutect2
- SLC17A4 | c.578C>A p.P193H | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64957445; called by muse, varscan2
- TUBB6 | c.106T>C p.Y36H | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.974); catalogued as COSV58354489; called by muse, mutect2, varscan2
- TXLNB | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.598); catalogued as rs375230246; called by muse, mutect2, varscan2
- ZNF423 | c.806A>G p.D269G (on ENST00000563137 / NM_001379286.1; = p.D261G on NM_015069.4) | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.094); catalogued as COSV52206164; called by muse, mutect2, varscan2
- ZNF512 | c.932G>A p.G311E | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV62673930; called by muse, mutect2, varscan2
- LIM2 | c.362G>C p.G121A (on ENST00000596399 / NM_001161748.2; = p.G163A on NM_030657.4) | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NF1 | c.4378_4381del p.H1460Cfs*8 (on ENST00000358273 / NM_001042492.3; = p.H1439Cfs*8 on NM_000267.3) | Frame Shift Del (DEL) | VAF 5/23 reads (22%) | called by mutect2, pindel, varscan2
- ARFGEF2 | c.1869C>T p.S623= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV64215620; called by muse, mutect2, varscan2
- CCDC81 | c.1776G>A p.A592= (on ENST00000445632 / NM_001156474.2; = p.A502= on NM_021827.4) | Silent (SNP) | VAF 106/2082 reads (5%) | catalogued as rs374757091; called by muse, mutect2
- DOCK7 | c.5349T>A p.A1783= (on ENST00000635253 / NM_001367561.1; = p.A1752= on NM_033407.3) | Silent (SNP) | VAF 39/121 reads (32%) | catalogued as COSV52023067; called by mutect2, varscan2
- DZIP3 | c.1623G>A p.G541= | Silent (SNP) | VAF 23/80 reads (29%) | catalogued as COSV64314121; called by muse, mutect2, varscan2
- PLCH1 | c.4218C>T p.N1406= (on ENST00000340059 / NM_001130960.2; = p.N1398= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 42/64 reads (66%) | catalogued as rs767980846, COSV58211149; called by mutect2, varscan2
- TECTA | c.1437G>A p.P479= | Silent (SNP) | VAF 32/78 reads (41%) | catalogued as rs140634094; ClinVar: likely benign; called by muse, mutect2, varscan2
- TMPRSS3 | c.846C>A p.A282= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as COSV52308567; called by mutect2, varscan2
